Somatic mutation profile of tumor specimen C3N-02696-02 (aliquot CPT0187720033) from CPTAC case C3N-02696, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 65.2 years (23,828 days).
Specimen C3N-02696-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18b2d8da-9599-4398-836b-df618fa9ca0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02696-31 (Blood Derived Normal), aliquot CPT0187770002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc9f2ea-d9b1-4237-bb45-d7ca6d6fc35a

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- REXO5 | c.157A>G p.I53V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs374414245; called by muse, mutect2
- USP17L2 | c.1227G>C p.K409N | Missense Mutation (SNP) | VAF 57/1733 reads (3%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as rs774997041, COSV100414518; called by muse, mutect2
- ANKRD26 | c.3855G>C p.E1285D | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2
- ZNF142 | c.2888C>T p.S963F (on ENST00000411696 / NM_001379660.1; = p.S763F on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); called by muse, mutect2
- GALNT12 | c.480T>G p.L160= | Silent (SNP) | VAF 9/196 reads (5%) | catalogued as COSV66663585; called by muse, mutect2
- WWC1 | c.3168G>A p.E1056= | Silent (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- CREBBP | c.-78G>T | 5'UTR (SNP) | VAF 11/85 reads (13%) | catalogued as rs940136901; called by muse, mutect2, varscan2
- TPO | c.2748+17C>T | Intron (SNP) | VAF 9/275 reads (3%) | catalogued as rs778044030; called by muse, mutect2
- XKR4 | c.806+58310C>T | Intron (SNP) | VAF 22/179 reads (12%) | catalogued as rs940389590, COSV100534470; called by muse, mutect2, varscan2
